Somatic mutation profile of tumor specimen TCGA-AN-A049-01A (aliquot TCGA-AN-A049-01A-21W-A019-09) from TCGA case TCGA-AN-A049, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.2 years (22,710 days).
Specimen TCGA-AN-A049-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b9db806-63cd-4ce6-b346-8b2d8545328c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A049-10A (Blood Derived Normal), aliquot TCGA-AN-A049-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c3545ef-65b6-4615-9d43-1ba9aa184288

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 24, Silent 7, Frame Shift Del 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 319/545 reads (59%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.8136dup p.D2713Rfs*10 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs761483896; ClinVar: pathogenic; called by pindel, varscan2
- CDC42BPA | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 159/349 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV62003387, COSV62003849; called by muse, mutect2, varscan2
- CUL4B | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV60685068; called by muse, mutect2, varscan2
- DOCK9 | c.6057C>A p.F2019L (on ENST00000376460 / NM_001366676.2; = p.F2020L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100240874; called by muse, mutect2
- ESYT1 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99920248; called by muse, mutect2
- GJB3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs763321092, COSV64904413; called by muse, mutect2, varscan2
- HEY1 | c.784T>A p.S262T | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV61232381; called by muse, mutect2, varscan2
- HOXA5 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs1190633462, COSV56072327; called by muse, mutect2, varscan2
- IRF4 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs1461930692, COSV66704517; called by muse, varscan2
- KCNH6 | c.1390G>T p.V464F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100121234; called by muse, mutect2
- MAP3K1 | c.2997_3000del p.D1000Sfs*81 | Frame Shift Del (DEL) | VAF 73/255 reads (29%) | catalogued as COSV68121938; called by mutect2, pindel, varscan2
- MDM1 | c.560G>T p.R187I | Missense Mutation (SNP) | VAF 164/518 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV57444652; called by muse, mutect2, varscan2
- NCDN | c.1607T>G p.I536S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV61934773; called by muse, mutect2, varscan2
- OCRL | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 171/601 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1305100597, COSV63980218; called by muse, mutect2, varscan2
- OGDHL | c.2345C>A p.P782H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV65101118; called by muse, mutect2, varscan2
- OR13G1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs780930216, COSV62943518; called by muse, mutect2, varscan2
- PRRC2C | c.4667G>A p.R1556Q (on ENST00000367742; = p.R1554Q on NM_015172.4) | Missense Mutation (SNP) | VAF 95/164 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs141606555; called by muse, mutect2, varscan2
- SEPTIN12 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750089256, COSV51615663; called by muse, mutect2, varscan2
- SIPA1L1 | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV62168413, COSV62168716; called by muse, mutect2, varscan2
- SYDE2 | c.775A>G p.M259V | Missense Mutation (SNP) | VAF 163/508 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs748125795, COSV52314252; called by muse, mutect2, varscan2
- TCN1 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 88/298 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.724); catalogued as rs778765850, COSV57252206; called by muse, mutect2, varscan2
- TOR1AIP2 | c.742A>C p.K248Q | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1415255197, COSV62625642; called by muse, varscan2
- WWC1 | c.2650G>A p.A884T | Missense Mutation (SNP) | VAF 223/430 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV54646377; called by muse, varscan2
- ZNF618 | c.455G>A p.C152Y (on ENST00000374126 / NM_001318042.2; = p.C120Y on NM_133374.2) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55916653; called by muse, mutect2, varscan2
- FBXO21 | c.598_626del p.V200Lfs*13 | Frame Shift Del (DEL) | VAF 58/316 reads (18%) | called by mutect2, varscan2
- FRMPD1 | c.2191G>C p.G731R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.296); called by muse, mutect2
- FSIP2 | c.19115del p.N6372Tfs*7 | Frame Shift Del (DEL) | VAF 42/161 reads (26%) | called by mutect2, pindel, varscan2
- KLHL15 | c.649dup p.T217Nfs*18 | Frame Shift Ins (INS) | VAF 294/1170 reads (25%) | called by mutect2, pindel, varscan2
- BARHL1 | c.48C>T p.R16= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs757098264, COSV55036748, COSV55037086; called by muse, mutect2, varscan2
- KRT2 | c.1023C>T p.R341= | Silent (SNP) | VAF 107/359 reads (30%) | catalogued as rs929319579, COSV59009220; called by muse, mutect2, varscan2
- PGD | c.996C>T p.I332= | Silent (SNP) | VAF 17/279 reads (6%) | catalogued as rs202058165, COSV54621545; called by muse, mutect2
- SLC12A9 | c.1164G>C p.V388= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as COSV51931564; called by muse, mutect2, varscan2
- SLFN12 | c.906C>T p.V302= | Silent (SNP) | VAF 185/552 reads (34%) | catalogued as COSV59225293; called by muse, mutect2, varscan2
- TNS2 | c.4104C>T p.F1368= (on ENST00000314250 / NM_170754.4; = p.F1378= on NM_015319.2) | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs771619962, COSV56852258; called by muse, mutect2, varscan2
- TTC37 | c.1713A>C p.G571= | Silent (SNP) | VAF 168/581 reads (29%) | catalogued as COSV62453564; called by muse, varscan2
